Somatic mutation profile of tumor specimen HTMCP-03-06-02409-01A (aliquot HTMCP-03-06-02409-01A-01D-10409) from CGCI case HTMCP-03-06-02409, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 40.7 years (14,881 days).
Specimen HTMCP-03-06-02409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81f6e37a-4276-4b28-b1ee-1aeb910251e5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02409-10A (Blood Derived Normal), aliquot HTMCP-03-06-02409-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7984dbf-b02b-4a5f-b8d9-72b00c382570

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP1A | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs377346518; called by mutect2, varscan2
- MAP4K3 | c.1166T>C p.L389S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs770599264; called by mutect2, varscan2
- MUC17 | c.8906C>T p.P2969L | Missense Mutation (SNP) | VAF 22/747 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1187193377; called by muse, mutect2
- ZNF749 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs367786292; called by muse, mutect2, varscan2
- AKAP11 | c.3977C>G p.S1326C | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2
- AKAP11 | c.4381C>G p.L1461V | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); called by muse, mutect2
- DNAH12 | c.7639G>A p.E2547K (on ENST00000351747; = p.E3415K on NM_001366028.2) | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2
- DNAH5 | c.13415T>G p.V4472G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- DYRK1A | c.226A>T p.M76L | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- FAT2 | c.7831G>A p.D2611N | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.8665G>C p.E2889Q | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HTATSF1 | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- KCNB2 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MAML2 | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 21/446 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2
- MED1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- MYPN | c.1798T>C p.F600L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); called by muse, mutect2
- NFATC3 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- SCN8A | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRRAP | c.2533G>T p.G845C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XIRP2 | c.7904C>G p.S2635C (on ENST00000628543; = p.S2810C on NM_152381.6) | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFR | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- CAPN1 | c.1551G>A p.K517= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- CCDC168 | c.4938C>T p.I1646= | Silent (SNP) | VAF 17/322 reads (5%) | called by muse, mutect2
- LRRN1 | c.1356G>A p.E452= | Silent (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- MYO18B | c.6666A>G p.E2222= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV59132010; called by mutect2, varscan2
- NCOR1 | c.1998T>C p.Y666= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
